Somatic mutation profile of tumor specimen BA2790D (aliquot aq-BA2790D) from BEATAML1.0 case 2171, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.0 years (24,098 days).
Specimen BA2790D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77322861-6a76-403a-8123-9e5f0dcad95c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2900D (Solid Tissue Normal), aliquot aq-BA2900D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2dfc5e0-4ec8-40cf-8358-7fe87353338c

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, 3'UTR 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 69/125 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CNGA3 | c.1117G>A p.V373M | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as rs552553452, COSV55624768; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KSR2 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs185272487, COSV56667008; called by muse, mutect2, varscan2
- LPAR3 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT tolerated (0.88); PolyPhen benign (0.031); catalogued as rs761209138; called by muse, mutect2, varscan2
- TLL1 | c.2491C>T p.H831Y | Missense Mutation (SNP) | VAF 13/325 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.634); catalogued as COSV50263048; called by muse, mutect2
- ZNF516 | c.1102C>G p.P368A | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1360333867; called by muse, mutect2, varscan2
- CLTC | c.2708G>A p.R903H | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.286); called by muse, mutect2
- LRP6 | c.2200T>A p.L734M | Missense Mutation (SNP) | VAF 139/239 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MARK2 | c.1721A>G p.N574S (on ENST00000402010 / NM_001039469.2; = p.N519S on NM_004954.5) | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, varscan2
- PSME4 | c.3837G>T p.W1279C | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RGS3 | c.2606C>A p.A869E (on ENST00000350696 / NM_001282923.2; = p.A588E on NM_130795.4) | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.138); called by muse, mutect2
- CADPS2 | c.1638C>T p.T546= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as rs549481301, COSV57382737; called by muse, mutect2, varscan2
- CBLL1 | c.555T>C p.H185= | Silent (SNP) | VAF 117/200 reads (59%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.1323C>A p.I441= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- ICE1 | c.1824T>C p.P608= | Silent (SNP) | VAF 57/181 reads (31%) | called by muse, mutect2, varscan2
- RIC1 | c.66T>C p.P22= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as rs1010033703; called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57610299 T>A | 5'Flank (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- FOXP2 | c.*187T>A | 3'UTR (SNP) | VAF 34/62 reads (55%) | called by muse, varscan2
- RASGRP1 | c.36-47C>T | Intron (SNP) | VAF 41/119 reads (34%) | catalogued as rs147065468; called by muse, mutect2, varscan2
